Somatic mutation profile of tumor specimen TCGA-IB-AAUQ-01A (aliquot TCGA-IB-AAUQ-01A-22D-A40W-08) from TCGA case TCGA-IB-AAUQ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 50.1 years (18,315 days).
Specimen TCGA-IB-AAUQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afee10b2-71ce-4188-aeab-77d9fae5d142.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-AAUQ-10A (Blood Derived Normal), aliquot TCGA-IB-AAUQ-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c6a01cd-9192-4b1c-bec9-30e9b3c04b12

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Intron 1, Nonsense Mutation 1, Translation Start Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 30/249 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 26/270 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ARHGAP18 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs940348303, COSV63764626; called by muse, mutect2
- ARHGEF11 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 47/461 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV100810275; called by muse, mutect2
- ASB4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 29/154 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99987186; called by muse, mutect2, varscan2
- BIRC6 | c.13120T>C p.S4374P | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101428483; called by muse, mutect2
- CACNG3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV50064715; called by muse, mutect2, varscan2
- CDH22 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100952933; called by muse, mutect2, varscan2
- CNTNAP2 | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753592463, COSV62240155; called by muse, mutect2, varscan2
- CR2 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 51/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889660, COSV65508724; called by muse, mutect2, varscan2
- CSPP1 | c.485A>T p.H162L (on ENST00000676605; = p.H121L on NM_024790.6) | Missense Mutation (SNP) | VAF 81/590 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV99139061; called by muse, mutect2, varscan2
- CYP2A6 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs58261757, COSV99991975; called by muse, mutect2, varscan2
- DLGAP5 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as rs761462822, COSV99904023; called by muse, mutect2
- DTX2 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 34/830 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs751158935, COSV100184719; called by muse, mutect2
- DUS3L | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100288341, COSV57833844; called by muse, mutect2
- EPHB2 | c.2803G>A p.A935T (on ENST00000400191 / NM_001309193.2; = p.A936T on NM_004442.7) | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.036); catalogued as rs757472320, COSV65862216; called by muse, mutect2, varscan2
- EVC | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs146028983; called by muse, mutect2, varscan2
- FADS3 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 69/513 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs144099007; called by muse, mutect2, varscan2
- FGF13 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs1264974671, COSV59542497; called by muse, mutect2, varscan2
- FOXI1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100089489, COSV100089586; called by muse, mutect2
- GBA2 | c.1943G>A p.C648Y | Missense Mutation (SNP) | VAF 29/360 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV100803441; called by muse, mutect2
- GDPGP1 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 54/465 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV100292105; called by muse, mutect2, varscan2
- KALRN | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV99565754; called by muse, mutect2
- KCNB2 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV73053652; called by muse, mutect2, varscan2
- KLRC3 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs370768044; called by muse, mutect2, varscan2
- KRT78 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs764925016, COSV58854161; called by muse, mutect2, varscan2
- KRTAP12-3 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 58/481 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs201241084, COSV59970464; called by muse, mutect2, varscan2
- LRIG1 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 21/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452065097, COSV56246630; called by muse, mutect2
- MYOT | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.421); catalogued as COSV99525025; called by muse, mutect2, varscan2
- OAS2 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1223147341, COSV100660238, COSV60803844; called by muse, mutect2, varscan2
- OPA1 | c.2284G>C p.E762Q (on ENST00000361510 / NM_130837.3; = p.E707Q on NM_015560.3) | Missense Mutation (SNP) | VAF 65/587 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as CM130780, COSV100655380; called by muse, mutect2, varscan2
- PAPPA | c.3751C>T p.R1251W | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs202058403, COSV60286591; called by muse, mutect2, varscan2
- PCDHA11 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 144/1262 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); catalogued as COSV100250180; called by muse, mutect2, varscan2
- PCDHB6 | c.2363G>A p.R788Q | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV99170471; called by muse, mutect2
- PDZRN4 | c.2042A>C p.Q681P (on ENST00000402685 / NM_001164595.2; = p.Q423P on NM_013377.4) | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100115011; called by muse, mutect2, varscan2
- PRSS38 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.231); catalogued as rs763201463, COSV100816326, COSV64541047; called by muse, mutect2, varscan2
- RDH5 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 98/891 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV99141819; called by muse, mutect2, varscan2
- SPEF2 | c.3853C>A p.P1285T | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100608061; called by muse, mutect2, varscan2
- SPG11 | c.4258A>T p.S1420C | Missense Mutation (SNP) | VAF 53/611 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV99969115; called by muse, mutect2
- TMC5 | c.2482C>T p.R828W (on ENST00000396229 / NM_001105248.1; = p.R582W on NM_024780.5) | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313580380, COSV54903714; called by muse, mutect2, varscan2
- TOMM22 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99320168; called by muse, mutect2, varscan2
- TOP2B | c.4630G>T p.A1544S (on ENST00000264331 / NM_001330700.2; = p.A1539S on NM_001068.3) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.519); catalogued as COSV99979988; called by muse, mutect2, varscan2
- TUBA3C | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 86/780 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as rs747244144, COSV67138980, COSV67140232; called by muse, mutect2, varscan2
- UBA2 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 87/608 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.129); catalogued as COSV99875680; called by muse, mutect2, varscan2
- VPS36 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV100955235; called by muse, mutect2, varscan2
- ZNF606 | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 51/572 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV100357451; called by muse, mutect2
- ACTN4 | c.932_946del p.R311_W315del | In Frame Del (DEL) | VAF 20/218 reads (9%) | called by mutect2, pindel
- SLIT1 | c.2180del p.G727Afs*65 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- CCDC80 | c.2712G>A p.A904= | Silent (SNP) | VAF 34/280 reads (12%) | catalogued as COSV99245019; called by muse, mutect2, varscan2
- CYP1A2 | c.678C>T p.F226= | Silent (SNP) | VAF 111/804 reads (14%) | catalogued as COSV59659773; called by muse, mutect2, varscan2
- DNAH5 | c.9975C>T p.C3325= | Silent (SNP) | VAF 67/496 reads (14%) | catalogued as rs771715883, COSV99451714; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EID2B | c.408C>T p.P136= | Silent (SNP) | VAF 68/735 reads (9%) | catalogued as COSV100411037; called by muse, mutect2
- FRY | c.8316C>T p.L2772= | Silent (SNP) | VAF 44/395 reads (11%) | catalogued as COSV100969559; called by muse, mutect2, varscan2
- HERC2 | c.4830G>A p.L1610= | Silent (SNP) | VAF 70/1379 reads (5%) | catalogued as COSV99875273; called by muse, mutect2
- KCNH2 | c.336G>A p.V112= | Silent (SNP) | VAF 49/270 reads (18%) | catalogued as COSV100060508; called by muse, mutect2, varscan2
- MEN1 | c.1410C>T p.A470= | Silent (SNP) | VAF 32/266 reads (12%) | catalogued as rs748820252, CD021425, COSV53645936; ClinVar: likely benign; called by muse, mutect2
- PCDHA6 | c.1611G>A p.A537= | Silent (SNP) | VAF 92/705 reads (13%) | catalogued as rs1295697160, COSV65344249; called by muse, mutect2, varscan2
- PCLO | c.192G>A p.Q64= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100434620; called by muse, mutect2
- PYCR3 | c.648G>A p.T216= | Silent (SNP) | VAF 32/264 reads (12%) | catalogued as rs1187338922, COSV99643577; called by muse, mutect2, varscan2
- RUNX3 | c.849G>A p.T283= | Silent (SNP) | VAF 39/404 reads (10%) | catalogued as rs779004787, COSV58244721; called by muse, mutect2, varscan2
- SMARCA2 | c.1131C>T p.T377= | Silent (SNP) | VAF 76/495 reads (15%) | catalogued as rs766651421, COSV61811040; called by muse, mutect2, varscan2
- OBSCN | c.18662-2933C>T | Intron (SNP) | VAF 7/72 reads (10%) | catalogued as rs1414591556, COSV52844529; called by muse, mutect2
